CPTAC case C3L-03377 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5ef77197-57b7-45ab-97dc-f83ec4e4dbec

Demographics
Sex at birth: female; Race: white; Year of birth: 1945; Vital status: Alive; Country of birth: Russia.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 73.0 years (26,673 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,109 days (3.0 years); Progression or recurrence: yes; Days to last follow up: 1,109 days (3.0 years); Clark level: IV; Tumor focality: Unifocal; Ulceration indicator: No.
   Pathology details: Breslow thickness category: >4.0 mm; Greatest tumor dimension: 2.5 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: Yes.

Follow-up (3 entries)
- Days to follow up: 377 days (1.0 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 765 days (2.1 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,109 days (3.0 years); Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 1.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 18; Cigarettes per day: 10; Tobacco smoking onset year: 1965; Tobacco smoking quit year: 2001; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 36.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03377-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 187 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03377-22: Section location: Extremities; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3L-03377-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 213 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-03377-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
